Gene-level copy-number profile of tumor specimen TCGA-06-0162-01A from TCGA case TCGA-06-0162, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.3 years (17,272 days).
Specimen TCGA-06-0162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.72b13da6-5a4e-4117-b883-e4b55ad49a66.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,090 have no estimate.
https://portal.gdc.cancer.gov/files/2a6285e0-3d38-4639-be9a-964a1696a9c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,985; copy number 2: 38,217; copy number 3: 2,703; copy number 4: 333; copy number 5: 14; copy number 6: 5; copy number 8: 6; copy number 11: 46; copy number 13: 78; copy number 14: 7; copy number 15: 139.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0162-01): tumor purity 0.67, ploidy 1.85, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 295 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:14,145,049–14,974,777, 1 gene, copy number 6 (within-gene range 4–6): DGKB.
- chr7:14,814,131–15,562,015, 4 genes, copy number 6 (within-gene range 2–6): AC006150.1, GTF3AP5, AC006458.1, AGMO.
- chr7:16,461,481–19,002,416, 33 genes, copy number 15 (within-gene range 2–15): SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1.
- chr7:20,615,207–20,777,038, 1 gene, copy number 5 (within-gene range 1–5): ABCB5.
- chr7:20,782,279–20,827,753, 2 genes, copy number 5: SP8, RPL23P8.
- chr7:20,843,627–20,843,961, 1 gene, copy number 5: RPS26P30.
- chr7:22,118,236–23,655,861, 38 genes, copy number 15: RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2.
- chr7:24,132,705–26,213,607, 32 genes, copy number 5–13: RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3.
- chr7:30,424,527–30,478,784, 1 gene, copy number 11 (within-gene range 2–11): NOD1.
- chr7:30,496,621–30,757,602, 11 genes, copy number 11 (within-gene range 3–11): GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1.
- chr7:31,414,158–32,457,758, 7 genes, copy number 13–15 (within-gene range 2–15): AC005090.1, ITPRID1, PPP1R17, PDE1C, SNX2P2, AC018637.1, AC018641.1.
- chr7:33,109,557–33,877,180, 1 gene, copy number 13 (within-gene range 2–13): BBS9.
- chr7:33,725,981–34,299,012, 8 genes, copy number 13: AC008080.1, AC008080.2, AC008080.4, AC008080.3, BMPER, AC007350.1, AC009262.1, RNU6-438P.
- chr7:54,721,724–55,260,256, 9 genes, copy number 5: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr12:57,546,026–59,064,238, 47 genes, copy number 15 (within-gene range 1–15): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:63,292,625–65,491,430, 58 genes, copy number 13: AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:66,037,235–68,234,686, 38 genes, copy number 11–15 (within-gene range 1–15): RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:71,835,034–71,927,248, 3 genes, copy number 11: AC089984.2, TBC1D15, MRS2P2.

Autosomal genes at a single copy (total copy number 1): 13,985. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
